Somatic mutation profile of tumor specimen TCGA-LD-A7W6-01A (aliquot TCGA-LD-A7W6-01A-81D-A351-09) from TCGA case TCGA-LD-A7W6, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating lobular mixed with other types of carcinoma; Tissue or organ of origin: Upper-inner quadrant of breast; AJCC pathologic stage: Stage IIB; Age at diagnosis: 55.0 years (20,077 days).
Specimen TCGA-LD-A7W6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bd2d603-1cbb-44f4-82be-53ff7d1b7828.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LD-A7W6-10A (Blood Derived Normal), aliquot TCGA-LD-A7W6-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a008a963-fdd5-4e2b-b64f-ae58e29630c7

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Nonsense Mutation 3, Splice Site 2, Intron 1, Frame Shift Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 46/98 reads (47%) | hotspot (GDC flag); catalogued as COSV55726950; called by muse, mutect2, varscan2
- AP4B1 | c.1873C>T p.Q625* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as COSV99870618; called by muse, mutect2, varscan2
- ATP11C | c.607G>T p.E203* | Nonsense Mutation (SNP) | VAF 5/65 reads (8%) | catalogued as COSV100557541; called by muse, mutect2
- AXDND1 | c.2815G>A p.A939T | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV100858268; called by muse, mutect2, varscan2
- DNAH17 | c.1322A>G p.E441G | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV101101627; called by muse, mutect2, varscan2
- DNM3 | c.1456A>T p.I486F | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100797832; called by muse, mutect2, varscan2
- DOCK9 | c.5230T>A p.Y1744N (on ENST00000376460 / NM_001366676.2; = p.Y1745N on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV100238200; called by muse, mutect2, varscan2
- DPPA2 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV101524742, COSV72117998; called by muse, mutect2
- GPR50 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.443); catalogued as rs768655839, COSV54442018; called by muse, mutect2, varscan2
- HROB | c.1943G>C p.*648Sext*30 | Nonstop Mutation (SNP) | VAF 21/67 reads (31%) | catalogued as COSV99809139; called by muse, mutect2, varscan2
- ITPKC | c.589A>G p.T197A | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); catalogued as COSV99648515; called by muse, mutect2, varscan2
- KDM6A | c.4176+2T>G p.X1392_splice | Splice Site (SNP) | VAF 6/88 reads (7%) | catalogued as COSV65045810, COSV65046410; called by muse, mutect2
- L3MBTL4 | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV99527745; called by muse, mutect2, varscan2
- MKRN3 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as COSV100090854; called by muse, mutect2, varscan2
- MYO7B | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768991281, COSV67348154; called by muse, mutect2, varscan2
- PLEKHG6 | c.1187C>T p.T396M | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs147609266; called by muse, mutect2, varscan2
- PODXL2 | c.1532T>C p.I511T | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV99229628; called by muse, mutect2, varscan2
- POLR3A | c.1348G>A p.V450I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.294); catalogued as rs1455388103, COSV100965557; called by muse, mutect2, varscan2
- QSOX2 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as rs376098174; called by muse, mutect2, varscan2
- UBXN6 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as rs8101961, COSV100010914; called by muse, mutect2, varscan2
- UNK | c.877A>T p.I293F | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99504614; called by muse, mutect2, varscan2
- MFSD14A | c.706-1_706del p.X236_splice | Splice Site (DEL) | VAF 11/57 reads (19%) | called by mutect2, pindel, varscan2
- ZFP36L1 | c.345_375del p.Y115* | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | called by mutect2, pindel
- LMAN1L | c.1335C>T p.A445= | Silent (SNP) | VAF 44/127 reads (35%) | catalogued as COSV100547596, COSV59002693; called by muse, mutect2, varscan2
- NDFIP2 | c.255T>G p.S85= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV99519149; called by muse, mutect2
- PARS2 | c.372G>A p.P124= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as rs767329181, COSV100988285; called by muse, mutect2, varscan2
- PCDHA6 | c.1614C>T p.R538= | Silent (SNP) | VAF 40/115 reads (35%) | catalogued as COSV100971279; called by muse, mutect2, varscan2
- TFE3 | c.792C>T p.V264= | Silent (SNP) | VAF 37/148 reads (25%) | catalogued as COSV100252381; called by muse, mutect2, varscan2
- XKR3 | c.730T>C p.L244= | Silent (SNP) | VAF 8/168 reads (5%) | catalogued as COSV100509152; called by muse, mutect2
- OPRM1 | c.1164+1897C>G | Intron (SNP) | VAF 25/47 reads (53%) | catalogued as COSV100000634; called by muse, mutect2, varscan2
